Somatic mutation profile of tumor specimen TCGA-A7-A26I-01B (aliquot TCGA-A7-A26I-01B-06D-A22N-09) from TCGA case TCGA-A7-A26I, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 65.6 years (23,948 days).
Specimen TCGA-A7-A26I-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1dc130c-c92b-49b2-900d-39e1d3c3a64a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A7-A26I-10A (Blood Derived Normal), aliquot TCGA-A7-A26I-10A-01D-A167-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a03aa09-08a0-4356-8c15-3803ea2eb378

The open-access MAF lists 33 somatic variants for this specimen: 28 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 4, Intron 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 8/16 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs193920774, CM1414506, COSV52664019, COSV52666760, COSV53585299; ClinVar: pathogenic / likely pathogenic / uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ADARB2 | c.391G>C p.V131L | Missense Mutation (SNP) | VAF 37/65 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV67229915; called by muse, mutect2, varscan2
- ALKBH2 | c.62A>G p.E21G | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV54356953; called by muse, mutect2, varscan2
- ASH1L | c.865A>G p.K289E | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as rs1239902334, COSV64208801, COSV64212930; called by muse, mutect2
- CCDC172 | c.605A>C p.E202A | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60939118; called by muse, mutect2, varscan2
- CEP135 | c.1528C>T p.R510C | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs778189963, COSV57262942; called by muse, mutect2, varscan2
- CHD7 | c.7756C>T p.P2586S | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV71112841; called by muse, mutect2, varscan2
- CLYBL | c.221G>C p.C74S | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59225133; called by muse, mutect2, varscan2
- COPA | c.2608C>T p.L870F | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.17); catalogued as COSV54106064; called by muse, mutect2, varscan2
- FRMD3 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV58465445; called by muse, mutect2, varscan2
- GGCT | c.67G>T p.G23C | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99139114; called by muse, mutect2
- GLMP | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV55296334; called by mutect2, varscan2
- HERC2 | c.3630A>G p.I1210M | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55337138; called by muse, mutect2, varscan2
- LGALS14 | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 21/74 reads (28%) | catalogued as rs763021205, COSV62373013; called by muse, mutect2, varscan2
- MOCOS | c.1085C>A p.S362Y | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV99732638, COSV99733375; called by muse, mutect2, varscan2
- NELL1 | c.127C>T p.L43F | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs770743919, COSV54293670; called by muse, varscan2
- NPAP1 | c.1603G>A p.V535I | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT tolerated (0.96); PolyPhen benign (0.266); catalogued as COSV61509022; called by muse, mutect2, varscan2
- OCRL | c.2456G>C p.R819P | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.037); catalogued as rs1312488743, COSV63981397; called by muse, mutect2, varscan2
- PEX5L | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as COSV55839615; called by muse, mutect2, varscan2
- POTEF | c.2009A>G p.Q670R | Missense Mutation (SNP) | VAF 157/337 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); catalogued as COSV62542487; called by muse, mutect2, varscan2
- PPEF1 | c.1670A>C p.H557P | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as COSV100583467; called by muse, mutect2
- SOX10 | c.767del p.P256Rfs*30 | Frame Shift Del (DEL) | VAF 25/68 reads (37%) | catalogued as COSV62807442; called by mutect2, pindel, varscan2
- SYT4 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as rs978828343; called by muse, mutect2, varscan2
- THAP10 | c.151T>A p.S51T | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV51436836; called by muse, mutect2
- TRIM25 | c.1604G>A p.R535Q | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367715143; called by muse, mutect2, varscan2
- TWNK | c.1858G>C p.E620Q | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.706); catalogued as COSV61327665; called by muse, mutect2, varscan2
- ZNF681 | c.1304C>T p.S435L | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.286); catalogued as rs1198882072, COSV68074976; called by muse, mutect2, varscan2
- IGKV1D-16 | c.203C>A p.S68Y | Missense Mutation (SNP) | VAF 34/273 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- DMBT1 | c.2196C>A p.T732= | Silent (SNP) | VAF 56/306 reads (18%) | catalogued as COSV57552193; called by muse, mutect2, varscan2
- FLOT2 | c.183G>T p.T61= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as COSV67528977, COSV67529266; called by muse, mutect2
- SEMA6D | c.1602C>A p.G534= | Silent (SNP) | VAF 4/64 reads (6%) | called by muse, mutect2
- TNKS2 | c.360A>G p.R120= | Silent (SNP) | VAF 11/95 reads (12%) | catalogued as COSV65416165; called by muse, mutect2, varscan2
- TTN | c.10360+2029A>T | Intron (SNP) | VAF 9/35 reads (26%) | catalogued as COSV60198356; called by muse, mutect2, varscan2
